Somatic mutation profile of tumor specimen ALCH-AC5N-TTP1-A (aliquot ALCH-AC5N-TTP1-A-1-0-D-A49D-36) from ALCHEMIST case ALCH-AC5N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,604 days).
Specimen ALCH-AC5N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f188a79b-225c-4675-9b72-02b262226309.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC5N-NB1-A (Blood Derived Normal), aliquot ALCH-AC5N-NB1-A-1-0-D-A49D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9152e741-20d2-414b-b96f-e1ca71eab23d

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Intron 2, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2256del p.L747_S752del | In Frame Del (DEL) | VAF 90/784 reads (11%) | hotspot (GDC flag); catalogued as rs121913440, COSV51767308, COSV51778874; ClinVar: drug response; called by mutect2, pindel
- ACP6 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV65078230; called by muse, mutect2
- ASTN1 | c.3799G>T p.E1267* | Nonsense Mutation (SNP) | VAF 20/472 reads (4%) | catalogued as COSV62500265; called by muse, mutect2
- B4GALT5 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 17/395 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1481119684; called by muse, mutect2
- CNGA3 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as CD152785; called by muse, mutect2
- FOXG1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 22/788 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV57395638; called by muse, mutect2
- PDGFRA | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 27/541 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.309); catalogued as COSV57272881; called by muse, mutect2
- PNMA3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs782014371; called by muse, mutect2
- RPL5 | c.283T>G p.Y95D | Missense Mutation (SNP) | VAF 62/472 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as CD108643; called by muse, mutect2, varscan2
- SYNE1 | c.16957G>A p.A5653T (on ENST00000367255 / NM_182961.4; = p.A5582T on NM_033071.3) | Missense Mutation (SNP) | VAF 46/776 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54975825; called by muse, mutect2
- DOCK7 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 14/335 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- ITPRIPL2 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMB2 | c.3070C>T p.P1024S | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.033); called by muse, mutect2
- METTL17 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 9/292 reads (3%) | called by muse, mutect2
- MYCBP2 | c.6682G>A p.D2228N (on ENST00000357337; = p.D2266N on NM_015057.5) | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PLEKHM1 | c.2838-1G>A p.X946_splice | Splice Site (SNP) | VAF 23/623 reads (4%) | called by muse, mutect2
- RBP3 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 43/901 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.597); called by muse, mutect2
- RFPL1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 25/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIMBP2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- SEM1 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 26/656 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.753); called by muse, mutect2
- SHLD3 | c.214T>A p.L72I | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.52); called by muse, mutect2
- TMC1 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 48/463 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, varscan2
- TRPC5 | c.2601T>G p.I867M | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CRHR2 | c.1167G>A p.R389= | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- DIPK2B | c.186C>T p.A62= | Silent (SNP) | VAF 22/316 reads (7%) | catalogued as rs768953800, COSV100933500; called by muse, mutect2
- GSTM1 | c.657G>A p.*219= | Silent (SNP) | VAF 53/558 reads (9%) | catalogued as rs765396532; called by muse, mutect2, varscan2
- LIMCH1 | c.1407C>T p.S469= | Silent (SNP) | VAF 22/543 reads (4%) | called by muse, mutect2
- MAP3K15 | c.2466C>T p.D822= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs748480121, COSV58839326; called by muse, mutect2, varscan2
- MTIF2 | c.1950G>A p.K650= | Silent (SNP) | VAF 8/217 reads (4%) | called by muse, mutect2
- SERPING1 | c.1230C>G p.L410= | Silent (SNP) | VAF 25/543 reads (5%) | catalogued as COSV99557972; called by muse, mutect2
- ZFHX4 | c.7665C>T p.S2555= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- CCL16 | c.-9G>A | 5'UTR (SNP) | VAF 6/117 reads (5%) | catalogued as rs370263354; called by muse, mutect2
- FLT4 | c.3893+755A>G | Intron (SNP) | VAF 16/490 reads (3%) | called by muse, mutect2
- GSTM1 | c.*1G>T | 3'UTR (SNP) | VAF 53/549 reads (10%) | catalogued as rs775566956; called by muse, mutect2, varscan2
- PDE4DIP | c.637-7009G>T | Intron (SNP) | VAF 8/76 reads (11%) | catalogued as rs1553497223; called by mutect2, varscan2
